Somatic mutation profile of tumor specimen CDDP-ABK9-TTP2-A (aliquot CDDP-ABK9-TTP2-A-1-0-D-A500-36) from CDDP_EAGLE case CDDP-ABK9, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 50 years.
Specimen CDDP-ABK9-TTP2-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6149d6e7-8bab-446b-85d4-6bd852d738c8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CDDP-ABK9-NB1-A (Blood Derived Normal), aliquot CDDP-ABK9-NB1-A-1-0-D-A500-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e443f0b7-a3eb-49ea-8b01-7f08e3d8e1ba

The open-access MAF lists 105 somatic variants for this specimen: 72 protein-altering or splice-affecting, 22 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 22, Nonsense Mutation 4, Splice Site 3, Frame Shift Del 3, 5'UTR 3, Intron 3, Splice Region 2, 5'Flank 2, 3'UTR 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.1026+2T>A p.X342_splice | Splice Site (SNP) | VAF 28/199 reads (14%) | hotspot (GDC flag); catalogued as COSV100910531, COSV64291630; called by muse, mutect2, varscan2
- ACTN2 | c.2044G>A p.E682K | Missense Mutation (SNP) | VAF 15/369 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100856573; called by muse, mutect2
- ATP4A | c.1253C>G p.S418* | Nonsense Mutation (SNP) | VAF 7/106 reads (7%) | catalogued as COSV52869615; called by muse, mutect2
- CACTIN | c.1559C>T p.A520V | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.028); catalogued as rs748577553, COSV50266772; called by muse, mutect2, varscan2
- CFAP45 | c.1392G>C p.E464D | Missense Mutation (SNP) | VAF 24/512 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.133); catalogued as COSV100928685; called by muse, mutect2
- CORO1A | c.1011C>G p.F337L | Missense Mutation (SNP) | VAF 35/391 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV99532256; called by muse, mutect2
- FCGBP | c.7342G>A p.V2448M | Missense Mutation (SNP) | VAF 33/674 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.395); catalogued as rs533092536; called by muse, mutect2
- GRIP1 | c.2074G>C p.E692Q (on ENST00000359742 / NM_001379345.1; = p.E640Q on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/294 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54022493; called by muse, mutect2
- HJV | c.1247C>G p.S416C (on ENST00000336751 / NM_213653.4; = p.S303C on NM_145277.5) | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV60951657, COSV60952213; called by muse, mutect2
- IAH1 | c.49C>G p.R17G | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV53012503; called by muse, mutect2
- ING1 | c.132G>C p.R44S | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.169); catalogued as COSV58168584; called by muse, mutect2
- N4BP2 | c.743C>G p.S248C | Missense Mutation (SNP) | VAF 24/260 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.72); catalogued as COSV54707968; called by muse, mutect2
- NALCN | c.4819C>T p.R1607W | Missense Mutation (SNP) | VAF 25/281 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs866709006, COSV51915914; called by muse, mutect2
- NKX3-2 | c.818C>T p.S273L | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.284); catalogued as rs891921365, COSV101219809; called by muse, mutect2
- NLRP2 | c.2797G>A p.G933R | Missense Mutation (SNP) | VAF 50/490 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs755680979, COSV54760442; called by muse, mutect2, varscan2
- PCDHA11 | c.917C>T p.T306I | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.043); catalogued as rs782441014; called by muse, mutect2
- PCDHB8 | c.1187C>T p.S396F | Missense Mutation (SNP) | VAF 53/464 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.595); catalogued as COSV50815884; called by muse, mutect2, varscan2
- PCDHGA9 | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.82); catalogued as rs867959669; called by muse, mutect2
- PHEX | c.1045G>T p.D349Y | Missense Mutation (SNP) | VAF 50/406 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV65074268; called by muse, mutect2, varscan2
- POTEB3 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 27/417 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1254735873; called by muse, mutect2
- SETD2 | c.1142del p.S381* | Frame Shift Del (DEL) | VAF 26/150 reads (17%) | catalogued as COSV100340601, COSV57434889; called by mutect2, pindel, varscan2
- SNX18 | c.1055G>A p.R352H | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.98); catalogued as COSV57987128; called by muse, mutect2, varscan2
- SPSB3 | c.635C>T p.S212L | Missense Mutation (SNP) | VAF 20/259 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV51601707; called by muse, mutect2
- TAF2 | c.1831G>A p.E611K | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65416442; called by muse, mutect2, varscan2
- TECPR1 | c.944G>A p.R315Q | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs552393733; called by muse, mutect2
- UPF3B | c.1369del p.D457Tfs*34 (on ENST00000276201 / NM_080632.3; = p.D444Tfs*34 on NM_023010.3) | Frame Shift Del (DEL) | VAF 36/307 reads (12%) | catalogued as COSV52231802; called by mutect2, pindel, varscan2
- UTP11 | c.496T>G p.F166V | Missense Mutation (SNP) | VAF 28/286 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.061); catalogued as COSV65951969; called by muse, mutect2
- VPS26B | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.297); catalogued as COSV55546435; called by muse, mutect2
- ZFP36L1 | c.895C>T p.L299F | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768617563; called by muse, mutect2, varscan2
- ZFYVE26 | c.3893C>A p.P1298Q | Missense Mutation (SNP) | VAF 8/208 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.346); catalogued as COSV61323770; called by muse, mutect2
- AADAT | c.846G>C p.E282D | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ACTL8 | c.622C>T p.Q208* | Nonsense Mutation (SNP) | VAF 25/356 reads (7%) | called by muse, mutect2
- ALKBH8 | c.1129C>G p.Q377E | Missense Mutation (SNP) | VAF 21/305 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, mutect2
- ARRB1 | c.742C>T p.Q248* | Nonsense Mutation (SNP) | VAF 9/230 reads (4%) | called by muse, mutect2
- C19orf84 | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- C3 | c.511G>T p.E171* | Nonsense Mutation (SNP) | VAF 42/444 reads (9%) | called by muse, mutect2
- CCDC30 | c.1350-2A>T p.X450_splice (on ENST00000340612; = p.X407_splice on NM_001080850.3) | Splice Site (SNP) | VAF 19/68 reads (28%) | called by muse, varscan2
- CCDC66 | c.1952G>A p.G651E (on ENST00000394672 / NM_001353147.1; = p.G617E on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CFAP45 | c.1639G>C p.A547P | Missense Mutation (SNP) | VAF 9/200 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2
- COPS2 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.021); called by muse, mutect2
- CRB1 | c.1426A>T p.T476S | Missense Mutation (SNP) | VAF 34/290 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- DEPDC5 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 9/243 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- DQX1 | c.1083G>C p.L361F | Missense Mutation (SNP) | VAF 9/170 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.348); called by muse, mutect2
- EDC3 | c.663G>C p.E221D | Missense Mutation (SNP) | VAF 52/353 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.383); called by muse, varscan2
- GMEB2 | c.621G>T p.V207= | Splice Region (SNP) | VAF 15/143 reads (10%) | called by muse, mutect2, varscan2
- HCFC1 | c.5621G>A p.R1874Q | Missense Mutation (SNP) | VAF 34/299 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- HIVEP2 | c.674C>G p.S225C | Missense Mutation (SNP) | VAF 25/220 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- INTS7 | c.1150C>A p.Q384K | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITSN2 | c.1834G>C p.E612Q | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.979); called by muse, mutect2
- MARCKSL1 | c.300G>C p.L100F | Missense Mutation (SNP) | VAF 7/164 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.377); called by muse, mutect2
- NUP205 | c.2016A>C p.I672= | Splice Region (SNP) | VAF 8/134 reads (6%) | called by muse, mutect2
- NXF1 | c.1543C>T p.R515W | Missense Mutation (SNP) | VAF 23/173 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR5W2 | c.392T>G p.L131R | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); called by muse, mutect2
- PDE12 | c.1636G>A p.E546K | Missense Mutation (SNP) | VAF 19/248 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.18); called by muse, mutect2
- PPFIBP2 | c.1901G>C p.W634S | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PPP4R2 | c.907G>C p.E303Q | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.047); called by muse, varscan2
- PRDM8 | c.1588G>A p.D530N | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- PRKCE | c.1834G>C p.E612Q | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RAI14 | c.2831C>T p.S944L | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.056); called by muse, mutect2
- RBM15 | c.1581_1582del p.D528Hfs*19 | Frame Shift Del (DEL) | VAF 17/133 reads (13%) | called by mutect2, pindel, varscan2
- RMND5A | c.763G>A p.D255N | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.072); called by muse, mutect2
- RP1 | c.908A>G p.E303G | Missense Mutation (SNP) | VAF 19/166 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- RYR1 | c.12682G>A p.E4228K | Missense Mutation (SNP) | VAF 15/250 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2
- SLC12A1 | c.2441G>C p.R814T | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); called by muse, mutect2
- SMC1B | c.2146C>G p.Q716E | Missense Mutation (SNP) | VAF 4/73 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.019); called by muse, mutect2
- STIP1 | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.158); called by muse, mutect2
- TET3 | c.529G>C p.D177H | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.599); called by muse, mutect2
- TTC30B | c.1563G>A p.M521I | Missense Mutation (SNP) | VAF 14/159 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.945); called by muse, mutect2
- TUBGCP6 | c.950G>C p.R317T | Missense Mutation (SNP) | VAF 17/334 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); called by muse, mutect2
- XRCC5 | c.454C>G p.H152D | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.014); called by muse, mutect2
- ZNF506 | c.3+1G>C p.X1_splice | Splice Site (SNP) | VAF 13/295 reads (4%) | called by muse, mutect2
- ZNF569 | c.1226C>A p.P409H | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANO4 | c.720G>A p.Q240= (on ENST00000392977 / NM_001286615.2; = p.Q205= on NM_178826.4) | Silent (SNP) | VAF 14/127 reads (11%) | called by muse, mutect2, varscan2
- BIN1 | c.216C>T p.V72= | Silent (SNP) | VAF 22/267 reads (8%) | called by muse, mutect2
- BOD1L1 | c.951A>G p.K317= | Silent (SNP) | VAF 33/314 reads (11%) | called by muse, varscan2
- CELF1 | c.1320G>C p.L440= (on ENST00000358597 / NM_001376422.1; = p.L436= on NM_006560.4 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 21/138 reads (15%) | called by muse, mutect2, varscan2
- DNAH9 | c.3738G>A p.P1246= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as rs192673174, COSV52347355; called by muse, mutect2, varscan2
- FUNDC2 | c.309G>A p.K103= | Silent (SNP) | VAF 14/183 reads (8%) | called by muse, mutect2
- GK | c.1428C>A p.G476= (on ENST00000427190 / NM_001205019.2; = p.G470= on NM_000167.6) | Silent (SNP) | VAF 14/490 reads (3%) | catalogued as COSV100970335; called by muse, mutect2
- NALCN | c.4476C>T p.F1492= | Silent (SNP) | VAF 8/108 reads (7%) | catalogued as COSV51921719; called by muse, mutect2
- NOL11 | c.750G>T p.L250= | Silent (SNP) | VAF 13/104 reads (13%) | called by muse, mutect2, varscan2
- NUMA1 | c.1809C>T p.L603= | Silent (SNP) | VAF 12/216 reads (6%) | called by muse, mutect2
- PHC3 | c.738T>C p.C246= (on ENST00000494943 / NM_001308116.2; = p.C258= on NM_024947.4) | Silent (SNP) | VAF 22/157 reads (14%) | called by muse, mutect2, varscan2
- PRELP | c.513G>C p.R171= | Silent (SNP) | VAF 13/250 reads (5%) | called by muse, mutect2
- RBBP7 | c.843T>C p.N281= | Silent (SNP) | VAF 32/378 reads (8%) | called by muse, mutect2
- RNF130 | c.1215C>T p.S405= | Silent (SNP) | VAF 9/195 reads (5%) | called by muse, mutect2
- SEMA6D | c.798C>G p.S266= | Silent (SNP) | VAF 43/349 reads (12%) | called by muse, mutect2, varscan2
- SERHL2 | c.402G>A p.P134= | Silent (SNP) | VAF 21/182 reads (12%) | catalogued as rs759133464, COSV100243447; called by muse, mutect2
- SRARP | c.504C>T p.A168= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as rs760246667, COSV61497799; called by muse, mutect2
- TRIP13 | c.912G>A p.K304= | Silent (SNP) | VAF 25/262 reads (10%) | called by muse, mutect2
- VPS41 | c.2283G>A p.K761= | Silent (SNP) | VAF 11/210 reads (5%) | called by muse, mutect2
- WASF2 | c.112C>A p.R38= | Silent (SNP) | VAF 10/307 reads (3%) | called by muse, mutect2
- WWC1 | c.2352C>T p.L784= | Silent (SNP) | VAF 10/137 reads (7%) | called by muse, mutect2
- ZNF469 | c.11235G>A p.R3745= (on ENST00000437464; = p.R3773= on NM_001367624.2) | Silent (SNP) | VAF 47/445 reads (11%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73847861 C>T | 5'Flank (SNP) | VAF 34/283 reads (12%) | called by muse, mutect2, varscan2
- AP1G2 | c.-60G>A | 5'UTR (SNP) | VAF 8/28 reads (29%) | catalogued as rs979322732, COSV58113041; called by muse, mutect2, varscan2
- BAIAP2 | chr17:81033067 G>C | 5'Flank (SNP) | VAF 42/508 reads (8%) | called by muse, mutect2
- KIR3DX1 | n.308G>A | RNA (SNP) | VAF 26/204 reads (13%) | catalogued as rs538252250; called by muse, mutect2, varscan2
- MMP13 | c.*19T>A | 3'UTR (SNP) | VAF 14/266 reads (5%) | called by muse, mutect2
- NCF2 | c.-26C>T | 5'UTR (SNP) | VAF 39/300 reads (13%) | catalogued as rs774655949; called by muse, mutect2, varscan2
- NHP2 | c.336+45C>T | Intron (SNP) | VAF 48/263 reads (18%) | catalogued as rs1219802346; called by muse, mutect2, varscan2
- SINHCAF | c.-21+776C>T | Intron (SNP) | VAF 21/114 reads (18%) | catalogued as rs1391142004, COSV58228910; called by muse, mutect2, varscan2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 22/138 reads (16%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2, varscan2
- VBP1 | c.219-46T>C | Intron (SNP) | VAF 9/114 reads (8%) | called by muse, mutect2
- VSX1 | chr20:25071697 C>G | 3'Flank (SNP) | VAF 21/348 reads (6%) | called by muse, mutect2
